Surgical pathology report (de-identified scan), TCGA case TCGA-61-2095, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2095-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: TUBE AND OVARY, RIGHT -

- A. MODERATELY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA OF THE OVARY.
- B. FALLOPIAN TUBE WITH SEROSAL INVOLVEMENT BY MODERATELY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA AND SHOWING MICROSCOPIC DETACHED FRAGMENTS OF TUMOR INVOLVING THE TUBAL LUMEN.

PART 2: UTERUS WITH LEFT ADNEXA, 180 GM. -

- A. MODERATELY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA INVOLVING UTERINE SEROSA AND EXTENDING INTO MYOMETRIAL VASCULAR SPACES.
- B. ENDOMETRIAL POLYP WITH FOCAL ATYPICAL COMPLEX HYPERPLASIA FOCALLY APPROACHING THE LEVEL OF WELL DIFFERENTIATED ADENOCARCINOMA OF THE ENDOMETRIUM.
- C. FOCAL COMPLEX HYPERPLASIA OF THE ENDOMETRIUM.
- D. MODERATELY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA INVOLVING THE LEFT OVARY AND SEROSA OF THE LEFT FALLOPIAN TUBE WITH FOCALLY PROMINENT PSAMMOMA BODIES.
- E. LEIOMYOMATA UTERI.
- F. ADENOMYOSIS UTERI.
- G. CERVIX WITH SMALL ENDOCERVICAL POLYP.

PART 3: OMENTUM AND TUMOR -

MATURE ADIPOSE TISSUE WITH METASTATIC MODERATELY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA.

Source: NCI Genomic Data Commons file cde95990-f81d-4c4b-aee1-4bfb554c97e0 (TCGA-61-2095.3E08408B-B76A-4A32-B3F1-4590459F4AF8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).